Somatic mutation profile of tumor specimen TCGA-VQ-A91Q-01A (aliquot TCGA-VQ-A91Q-01A-12D-A410-08) from TCGA case TCGA-VQ-A91Q, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 61.1 years (22,303 days).
Specimen TCGA-VQ-A91Q-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8134a758-7cf2-43aa-9ab1-92e1fb9054dd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VQ-A91Q-10A (Blood Derived Normal), aliquot TCGA-VQ-A91Q-10A-01D-A413-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5e54ac6b-9a2e-42f7-8454-07c5b5c5f7ea

The open-access MAF lists 110 somatic variants for this specimen: 82 protein-altering or splice-affecting, 25 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 70, Silent 25, Nonsense Mutation 6, 5'UTR 2, Frame Shift Ins 2, Splice Site 2, Splice Region 1, RNA 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKAR | c.745T>G p.F249V | Missense Mutation (SNP) | VAF 85/286 reads (30%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.895); catalogued as COSV99854136; called by muse, mutect2, varscan2
- ARHGAP25 | c.721C>T p.R241* (on ENST00000409202 / NM_001007231.3; = p.R233* on NM_014882.3) | Nonsense Mutation (SNP) | VAF 27/99 reads (27%) | catalogued as rs925122050, COSV99771390; called by muse, mutect2, varscan2
- ARHGEF28 | c.1401G>C p.K467N | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.14); catalogued as COSV99708837; called by muse, mutect2
- BBS9 | c.1438G>A p.D480N | Missense Mutation (SNP) | VAF 60/158 reads (38%) | SIFT tolerated (0.42); PolyPhen benign (0.029); catalogued as COSV99627593; called by muse, mutect2, varscan2
- BRPF1 | c.3086C>T p.S1029F | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); catalogued as COSV100115300; called by muse, mutect2, varscan2
- CACNA2D4 | c.2028C>A p.H676Q | Missense Mutation (SNP) | VAF 44/164 reads (27%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as COSV99765501; called by muse, mutect2, varscan2
- CARHSP1 | c.400G>C p.G134R | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.827); catalogued as COSV100220182; called by muse, mutect2, varscan2
- CASP8AP2 | c.730A>T p.R244* | Nonsense Mutation (SNP) | VAF 64/202 reads (32%) | catalogued as COSV99386988; called by muse, mutect2, varscan2
- CD36 | c.295G>A p.A99T | Missense Mutation (SNP) | VAF 34/143 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.077); catalogued as COSV99987411; called by muse, mutect2, varscan2
- CDKL2 | c.34G>T p.E12* | Nonsense Mutation (SNP) | VAF 8/126 reads (6%) | catalogued as COSV100276868; called by muse, mutect2
- CETP | c.715G>A p.V239I | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs767196975, COSV52361991; called by muse, mutect2, varscan2
- CPXM2 | c.1736A>T p.E579V | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.24); PolyPhen benign (0.015); catalogued as COSV99581916; called by muse, mutect2, varscan2
- DDR2 | c.2303G>C p.S768T | Missense Mutation (SNP) | VAF 96/275 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV100906455; called by muse, mutect2, varscan2
- DPY19L2 | c.1403C>T p.T468I | Missense Mutation (SNP) | VAF 38/226 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.477); catalogued as COSV100116684; called by muse, mutect2, varscan2
- EPB41L4B | c.497C>A p.S166Y | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101000504; called by muse, mutect2, varscan2
- FAM189A2 | c.47T>G p.V16G | Missense Mutation (SNP) | VAF 39/85 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as COSV99974952; called by muse, mutect2, varscan2
- FAM98A | c.85C>T p.L29F | Missense Mutation (SNP) | VAF 37/115 reads (32%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.998); catalogued as rs775628082, COSV99479218; called by muse, mutect2, varscan2
- FANCD2 | c.1579C>T p.Q527* | Nonsense Mutation (SNP) | VAF 23/103 reads (22%) | catalogued as COSV99811095; called by muse, mutect2, varscan2
- FAT2 | c.1658A>T p.Q553L | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as COSV99942541; called by muse, mutect2, varscan2
- FERMT2 | c.1670G>A p.R557K | Missense Mutation (SNP) | VAF 44/72 reads (61%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.657); catalogued as COSV100448853; called by muse, mutect2, varscan2
- FLT1 | c.1678C>G p.H560D | Missense Mutation (SNP) | VAF 27/104 reads (26%) | SIFT tolerated (0.53); PolyPhen benign (0.031); catalogued as COSV99151644; called by muse, mutect2, varscan2
- GOLGA4 | c.2279A>T p.Q760L | Missense Mutation (SNP) | VAF 41/116 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.109); catalogued as COSV100728825; called by muse, mutect2, varscan2
- HARBI1 | c.449G>A p.C150Y | Missense Mutation (SNP) | VAF 94/268 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.84); catalogued as rs745384168, COSV100365687; called by muse, mutect2, varscan2
- HEATR1 | c.1576T>G p.L526V | Missense Mutation (SNP) | VAF 40/108 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV100857602; called by muse, mutect2, varscan2
- HHIPL2 | c.2146C>A p.Q716K | Missense Mutation (SNP) | VAF 169/437 reads (39%) | SIFT tolerated, low confidence (0.89); PolyPhen benign (0.007); catalogued as COSV100596795; called by muse, mutect2, varscan2
- HTT | c.7459A>T p.S2487C | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.491); catalogued as COSV100750674; called by muse, mutect2, varscan2
- IFIT1B | c.120G>T p.W40C | Missense Mutation (SNP) | VAF 38/120 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV100879072; called by muse, mutect2, varscan2
- IGHV3-72 | c.269C>T p.T90I | Missense Mutation (SNP) | VAF 60/178 reads (34%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.503); catalogued as rs752206687, COSV70409680; called by muse, mutect2, varscan2
- KDM2B | c.3895G>T p.D1299Y | Missense Mutation (SNP) | VAF 32/197 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV100997381; called by muse, mutect2, varscan2
- KDM5D | c.1074C>G p.C358W | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100522199; called by muse, mutect2, varscan2
- KIAA1549 | c.3800G>T p.R1267I | Missense Mutation (SNP) | VAF 79/143 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99650571; called by muse, mutect2, varscan2
- KIAA1549L | c.824A>G p.N275S (on ENST00000321505; = p.N572S on NM_012194.3) | Missense Mutation (SNP) | VAF 8/115 reads (7%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.012); catalogued as COSV99683287; called by muse, mutect2
- KMO | c.530T>A p.L177Q | Missense Mutation (SNP) | VAF 48/127 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100844801; called by muse, mutect2, varscan2
- KMT2D | c.1459C>T p.R487W | Missense Mutation (SNP) | VAF 50/118 reads (42%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.026); catalogued as rs367559440; called by muse, mutect2, varscan2
- LAMA2 | c.2998G>T p.A1000S | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT tolerated (0.29); PolyPhen benign (0.431); catalogued as COSV101370370; called by muse, mutect2, varscan2
- LMTK2 | c.473C>T p.T158M | Missense Mutation (SNP) | VAF 66/299 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs775318231, COSV51999720, COSV52004831; called by muse, mutect2, varscan2
- MAGEB10 | c.387A>T p.K129N | Missense Mutation (SNP) | VAF 36/49 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100775244; called by muse, mutect2, varscan2
- MASP1 | c.992C>G p.T331R | Missense Mutation (SNP) | VAF 103/229 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.211); catalogued as COSV99397094; called by muse, mutect2, varscan2
- MS4A4A | c.317G>A p.W106* | Nonsense Mutation (SNP) | VAF 39/151 reads (26%) | catalogued as COSV100557762, COSV59701968; called by muse, mutect2, varscan2
- MYLK | c.3373C>G p.P1125A | Missense Mutation (SNP) | VAF 36/113 reads (32%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.815); catalogued as COSV100658922, COSV60619762; called by muse, mutect2, varscan2
- MYOF | c.3781G>A p.G1261R | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs370780451, COSV63700587; called by muse, mutect2, varscan2
- OGFOD1 | c.598C>G p.L200V | Missense Mutation (SNP) | VAF 79/270 reads (29%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.627); catalogued as COSV100272995; called by muse, mutect2, varscan2
- PAPOLB | c.1522G>T p.A508S | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV101271360; called by muse, mutect2, varscan2
- PAX1 | c.719C>T p.P240L | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.04); catalogued as COSV68273850; called by muse, mutect2, varscan2
- PDGFRA | c.294C>A p.Y98* | Nonsense Mutation (SNP) | VAF 12/229 reads (5%) | catalogued as COSV57268134; called by muse, mutect2
- PLCZ1 | c.590G>A p.R197H | Missense Mutation (SNP) | VAF 16/146 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781075636, COSV56859649; called by muse, mutect2, varscan2
- PPP1R1B | c.295A>C p.N99H | Missense Mutation (SNP) | VAF 47/176 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as COSV99566198; called by muse, mutect2, varscan2
- PTPRM | c.3943G>T p.V1315F | Missense Mutation (SNP) | VAF 19/122 reads (16%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.995); catalogued as COSV100156732; called by muse, mutect2, varscan2
- RBM27 | c.2939T>A p.V980D | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as COSV99506047; called by muse, mutect2, varscan2
- ROBO2 | c.3233dup p.V1079Sfs*22 | Frame Shift Ins (INS) | VAF 14/64 reads (22%) | catalogued as rs745519558; called by mutect2, varscan2
- SCN2A | c.1780G>A p.A594T | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.999); catalogued as COSV99331202; called by muse, mutect2, varscan2
- SCN3A | c.1751C>A p.A584E | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT tolerated (0.31); PolyPhen benign (0.326); catalogued as COSV99326605; called by muse, mutect2, varscan2
- SCTR | c.534C>A p.H178Q | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99191562; called by muse, mutect2, varscan2
- SDC2 | c.155C>T p.A52V | Missense Mutation (SNP) | VAF 52/206 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.341); catalogued as COSV100143299; called by muse, mutect2
- SEL1L3 | c.1855G>C p.G619R | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs922731133, COSV99340065, COSV99341282; called by muse, mutect2, varscan2
- SH3BP4 | c.316T>C p.S106P | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.799); catalogued as COSV100749116; called by muse, mutect2, varscan2
- SLC17A8 | c.1393C>G p.P465A | Missense Mutation (SNP) | VAF 59/110 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100035445; called by muse, mutect2, varscan2
- SLC20A1 | c.1829T>A p.V610E | Missense Mutation (SNP) | VAF 28/117 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99734017; called by muse, mutect2, varscan2
- SLC4A10 | c.1906T>A p.F636I (on ENST00000446997 / NM_001354461.2; = p.F606I on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99763533; called by muse, varscan2
- SRGAP1 | c.173A>T p.E58V | Missense Mutation (SNP) | VAF 72/1248 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100754546; called by muse, mutect2
- ST7L | c.1198G>A p.V400M | Missense Mutation (SNP) | VAF 29/213 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.903); catalogued as rs201867659, COSV58309381; called by muse, mutect2, varscan2
- TBC1D1 | c.1595G>A p.S532N | Missense Mutation (SNP) | VAF 23/141 reads (16%) | SIFT tolerated (0.4); PolyPhen benign (0.066); catalogued as COSV99791038; called by muse, mutect2, varscan2
- THRAP3 | c.2695C>T p.R899W | Missense Mutation (SNP) | VAF 27/110 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs201119618; called by muse, mutect2, varscan2
- THSD7B | c.4639C>T p.L1547F (on ENST00000272643; = p.L1545F on NM_001316349.2) | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.046); catalogued as COSV99748963; called by muse, mutect2, varscan2
- TREML1 | c.570G>A p.G190= | Splice Region (SNP) | VAF 6/27 reads (22%) | catalogued as rs1342592727, COSV100914284; called by muse, mutect2, varscan2
- TREML1 | c.569G>A p.G190E | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as COSV64191678; called by muse, mutect2, varscan2
- TRIM41 | c.618G>C p.Q206H | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.753); catalogued as COSV100163164; called by muse, mutect2, varscan2
- TTC32 | c.34C>G p.L12V | Missense Mutation (SNP) | VAF 42/169 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as COSV100367805; called by muse, mutect2, varscan2
- USH2A | c.3271A>T p.R1091W | Missense Mutation (SNP) | VAF 40/121 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56403385; called by muse, mutect2, varscan2
- USP31 | c.1796C>G p.S599C | Missense Mutation (SNP) | VAF 124/374 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV54853010, COSV99565037; called by muse, mutect2, varscan2
- UXS1 | c.368C>T p.T123M | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs1327555218, COSV51680035; called by muse, mutect2, varscan2
- VGLL1 | c.320C>T p.P107L | Missense Mutation (SNP) | VAF 214/282 reads (76%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV101034594; called by muse, mutect2, varscan2
- WARS2 | c.215G>A p.S72N | Missense Mutation (SNP) | VAF 74/171 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV99346250; called by muse, mutect2, varscan2
- WDR49 | c.767+1G>T p.X256_splice (on ENST00000308378 / NM_001366158.1; = p.X597_splice on NM_001348951.2 and 2 other RefSeq transcripts) | Splice Site (SNP) | VAF 48/173 reads (28%) | catalogued as rs1292399396, COSV100391624; called by muse, mutect2, varscan2
- ZBTB14 | c.172A>T p.S58C | Missense Mutation (SNP) | VAF 52/166 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100813442; called by muse, mutect2
- ZC3H13 | c.2983A>G p.K995E | Missense Mutation (SNP) | VAF 85/245 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.194); catalogued as COSV99667983; called by muse, mutect2, varscan2
- ZFP30 | c.335G>C p.C112S | Missense Mutation (SNP) | VAF 38/125 reads (30%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV100665872; called by muse, mutect2, varscan2
- ZNF431 | c.3+1G>T p.X1_splice | Splice Site (SNP) | VAF 39/144 reads (27%) | catalogued as COSV100218647; called by muse, mutect2, varscan2
- ZNF655 | c.643G>A p.D215N | Missense Mutation (SNP) | VAF 6/136 reads (4%) | SIFT tolerated (0.97); PolyPhen benign (0.097); catalogued as COSV99402087; called by muse, mutect2
- ZNF711 | c.1220A>G p.D407G | Missense Mutation (SNP) | VAF 13/18 reads (72%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.815); catalogued as COSV99340951; called by muse, mutect2, varscan2
- CABIN1 | c.1630_1632dup p.M544dup | In Frame Ins (INS) | VAF 34/84 reads (40%) | called by mutect2, pindel, varscan2
- DOK4 | c.625dup p.Y209Lfs*81 | Frame Shift Ins (INS) | VAF 26/90 reads (29%) | called by mutect2, pindel, varscan2
- ABCA13 | c.2820A>G p.E940= | Silent (SNP) | VAF 42/126 reads (33%) | catalogued as COSV70025519, COSV70028233; called by muse, mutect2, varscan2
- AUTS2 | c.2457G>A p.A819= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as rs1309064482, COSV100716253; called by muse, mutect2, varscan2
- CASP7 | c.873G>T p.V291= | Silent (SNP) | VAF 53/180 reads (29%) | catalogued as COSV100614865; called by muse, mutect2, varscan2
- CDH13 | c.1548T>G p.V516= | Silent (SNP) | VAF 11/278 reads (4%) | catalogued as COSV99224930; called by muse, mutect2
- DLK2 | c.1011C>T p.C337= | Silent (SNP) | VAF 8/47 reads (17%) | catalogued as rs1410526041, COSV55085460, COSV99767135; called by muse, mutect2, varscan2
- FATE1 | c.303C>T p.Y101= | Silent (SNP) | VAF 11/53 reads (21%) | catalogued as rs779571906, COSV100948142, COSV64849384; called by muse, mutect2, varscan2
- GATA6 | c.492C>G p.G164= | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as COSV99333133; called by muse, mutect2
- GFPT2 | c.1872C>T p.D624= | Silent (SNP) | VAF 10/118 reads (8%) | catalogued as rs371527867; ClinVar: likely benign; called by muse, mutect2
- GPR141 | c.90C>T p.G30= | Silent (SNP) | VAF 63/189 reads (33%) | catalogued as rs368456046; called by muse, mutect2, varscan2
- IRS4 | c.2400T>C p.S800= | Silent (SNP) | VAF 68/127 reads (54%) | catalogued as COSV100929522; called by muse, mutect2, varscan2
- KNL1 | c.5730G>A p.Q1910= (on ENST00000346991 / NM_170589.5; = p.Q1884= on NM_144508.5) | Silent (SNP) | VAF 29/94 reads (31%) | catalogued as rs1466257793, COSV100706338; called by muse, mutect2, varscan2
- MED1 | c.1380C>T p.D460= | Silent (SNP) | VAF 20/106 reads (19%) | catalogued as COSV100327728; called by muse, mutect2, varscan2
- NCOR1 | c.2295C>G p.P765= | Silent (SNP) | VAF 41/76 reads (54%) | catalogued as COSV51989973, COSV99251792; called by muse, mutect2, varscan2
- PCDHA10 | c.1554G>A p.A518= | Silent (SNP) | VAF 70/239 reads (29%) | catalogued as COSV100248197; called by muse, mutect2, varscan2
- PLCL1 | c.2343T>G p.T781= | Silent (SNP) | VAF 55/188 reads (29%) | catalogued as COSV70824160, COSV70870375; called by muse, mutect2, varscan2
- POC1A | c.645C>T p.D215= | Silent (SNP) | VAF 11/35 reads (31%) | catalogued as rs374642866; called by muse, mutect2, varscan2
- RERG | c.180C>T p.D60= | Silent (SNP) | VAF 68/182 reads (37%) | catalogued as COSV99917292; called by muse, mutect2, varscan2
- SAFB | c.2370C>T p.H790= | Silent (SNP) | VAF 44/182 reads (24%) | catalogued as rs373577698; called by muse, mutect2, varscan2
- SEMA5A | c.3204C>G p.L1068= | Silent (SNP) | VAF 23/90 reads (26%) | catalogued as COSV101227902; called by muse, mutect2, varscan2
- SLC4A10 | c.1860C>T p.I620= (on ENST00000446997 / NM_001354461.2; = p.I590= on NM_022058.4 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 30/82 reads (37%) | catalogued as COSV99763527; called by muse, varscan2
- TMC5 | c.1824G>A p.T608= (on ENST00000396229 / NM_001105248.1; = p.T362= on NM_024780.5) | Silent (SNP) | VAF 55/152 reads (36%) | catalogued as rs758587271, COSV54909933, COSV54911389; called by muse, mutect2, varscan2
- TPRN | c.1023G>T p.G341= | Silent (SNP) | VAF 9/24 reads (38%) | catalogued as rs1212957767, COSV100285780; called by muse, mutect2, varscan2
- TPSD1 | c.99G>A p.L33= | Silent (SNP) | VAF 28/104 reads (27%) | catalogued as rs1211726609, COSV99273800; called by muse, mutect2, varscan2
- ZBBX | c.1794T>C p.F598= | Silent (SNP) | VAF 55/258 reads (21%) | catalogued as rs756228254, COSV100283842; called by muse, mutect2, varscan2
- ZNF567 | c.1374C>T p.F458= (on ENST00000536254 / NM_001322913.1; = p.F427= on NM_152603.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 22/125 reads (18%) | catalogued as COSV62445813; called by muse, mutect2, varscan2
- CISD1 | c.-1C>G | 5'UTR (SNP) | VAF 20/55 reads (36%) | catalogued as COSV100445693; called by muse, mutect2, varscan2
- HADHB | c.-2G>A | 5'UTR (SNP) | VAF 56/148 reads (38%) | catalogued as rs773419302, COSV100501981; called by mutect2, varscan2
- RNF217-AS1 | n.1201A>C | RNA (SNP) | VAF 43/98 reads (44%) | called by muse, mutect2, varscan2
